Gene-level copy-number profile of tumor specimen TCGA-CH-5752-01A from TCGA case TCGA-CH-5752, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.5 years (24,290 days).
Specimen TCGA-CH-5752-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.43bc5e56-b062-4fd3-9523-a3e9c43ff31d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CH-5752-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d9a503e5-2090-4b70-bdc5-a9da97824975

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 112; copy number 1: 3,996; copy number 2: 55,559; copy number 3: 153.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CH-5752-01A-11D-1574-01): tumor purity 0.79, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 112 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:25,061,626–25,452,263, 1 gene (within-gene range 0–1): CMAHP.
- chr6:25,140,003–26,574,698, 84 genes (broad region; genes not listed).
- chr6:27,211,244–27,781,111, 24 genes: RPL10P2, PRSS16, AL021808.1, POM121L2, VN1R10P, ZNF204P, ZNF391, AL031118.1, MCFD2P1, ZNF184, AL021918.4, AL021918.5, AL021918.3, AL021918.2, AL021918.1, HNRNPA1P1, CD83P1, RNU6-471P, RPL8P1, AL009179.2, LINC01012, GPR89P, AL009179.1, RSL24D1P1.
- chr15:56,887,107–57,299,281, 3 genes (within-gene range 0–1): AC010999.2, AC010999.1, TCF12.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,615. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
